Somatic mutation profile of tumor specimen MP2PRT-PAVPDH-TMP1-A (aliquot MP2PRT-PAVPDH-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVPDH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,396 days).
Specimen MP2PRT-PAVPDH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 139ee9d0-49ed-4d66-9a6e-4843cb5420f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPDH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPDH-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f72592f-74e8-4388-878c-50eaddfd2d69

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALML5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs199855788, COSV100981195; called by muse, varscan2
- CFAP46 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs911871805; called by muse, mutect2, varscan2
- EPHB4 | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367628554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHLH1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 136/310 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57484591; called by muse, mutect2, varscan2
- TGM1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.953); catalogued as rs753328770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN2 | c.3193C>T p.L1065F (on ENST00000313400 / NM_001365069.1; = p.L1014F on NM_014010.5) | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHV3-66 | c.345_346insTGGGGAGGAGAGATCG p.R116Wfs*? | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | called by pindel, varscan2
- BTBD1 | c.1170C>T p.T390= | Silent (SNP) | VAF 98/196 reads (50%) | called by muse, mutect2, varscan2
